Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A3PT, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A3PT-01A (Primary Tumor).

Collection Date

FINAL DIAGNOSIS:

PART 1: THYROID, RIGHT LOBE, LOBECTOMY (11 GRAMS) -

- A. MULTIFOCAL PAPILLARY THYROID CARCINOMA (AT LEAST 5 FOCI RANGING IN SIZE FROM 0.4 TO 1.1 CM), FOLLICULAR VARIANT.
- B. FOCAL EXTRATHYROIDAL EXTENSION PRESENT WITH FOCAL EXTENSION TO RESECTION MARGIN.
- C. NO ANGIOLYMPHATIC INVASION SEEN.
- D. PATHOLOGIC STAGE; T3 NX.

PART 2: THYROID, LEFT LOBE, LOBECTOMY (10 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA (1.5 CM), FOLLICULAR VARIANT.
- B. THE TUMOR IS CONFINED TO THE THYROID AND RESECTION MARGINS ARE FREE OF TUMOR.
- C. NO ANGIOLYMPHATIC INVASION SEEN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Right Lobe, Left Lobe
TUMOR FOCALITY:	Multifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 1.5 cm
HISTOLOGIC TYPE**:	Papillary carcinoma, follicular variant, non-encapsulated
PRIMARY TUMOR (pT):	pT3
REGIONAL LYMPH NODES (pN):	pNX
	Number of regional lymph nodes examined: 0
	Number of regional lymph nodes involved: 0
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Present
MARGINS:	Margin(s) involved by carcinoma
LYMPH-VASCULAR INVASION:	Not identified

Addendum

MOLECULAR ANATOMIC PATHOLOGY TESTING:

Block 2A:

- A. *HRAS* codon 61 mutation IDENTIFIED.
- B. Mutations in *BRAF*, *NRAS61*, *KRAS12/13* and *RET/PTC1* and *RET/PTC3* rearrangements NOT identified.

ICD-O-3

Carcinoma, papillary, follicular variant 8340/3
Site: Thyroid, NOS c 73.9

W 3/9/12

Source: NCI Genomic Data Commons file fefffa7f-d86f-4e83-b216-1a0fb0cd059f (TCGA-BJ-A3PT.25BA0C46-3556-494D-9BAA-FE4B153AF812.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).